Gene-level copy-number profile of tumor specimen TCGA-D7-A6EX-01A from TCGA case TCGA-D7-A6EX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.6 years (26,525 days).
Specimen TCGA-D7-A6EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5b8b1ef2-edd6-40e6-9237-fca8b45bad89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A6EX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c22271c4-aa2a-432c-a114-7eca6a73e300

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,713; copy number 2: 27,851; copy number 3: 15,160; copy number 4: 9,075; copy number 5: 2,353; copy number 6: 850; copy number 7: 297; copy number 8: 224; copy number 9: 75; copy number 10: 2; copy number 11: 66; copy number 12: 2; copy number 13: 1; copy number 23: 19; copy number 26: 1; copy number 32: 6; copy number 33: 25; copy number 40: 80; copy number 43: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A6EX-01A-11D-A31K-01): tumor purity 0.77, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,013 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–145,996,579, 99 genes, copy number 5 (broad region; genes not listed).
- chr1:171,444,699–207,416,236, 658 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–7,830,081, 152 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr7:63,011,463–93,148,385, 564 genes, copy number 7–43 (broad region; genes not listed).
- chr8:127,253,213–127,742,951, 9 genes, copy number 5: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr9:27,102,630–29,826,711, 26 genes, copy number 6: AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:35,360,540–37,358,149, 78 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:44,712–123,697,399, 2,149 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr10:124,397,303–133,761,125, 173 genes, copy number 5 (broad region; genes not listed).
- chr12:18,080,869–25,409,445, 102 genes, copy number 9–40 (within-gene range 4–40) (broad region; genes not listed).
- chr12:25,423,600–25,441,052, 3 genes, copy number 40: AC092451.2, FAM133GP, TUBB4BP1.

Autosomal genes at a single copy (total copy number 1): 1,843. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
